Somatic mutation profile of tumor specimen TARGET-40-NAAGJY-01A (aliquot TARGET-40-NAAGJY-01A-01D) from TARGET case TARGET-40-NAAGJY, project TARGET-OS (Osteosarcoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Osteosarcoma, NOS; Tissue or organ of origin: Long bones of lower limb and associated joints; Age at diagnosis: 10.7 years (3,922 days).
Specimen TARGET-40-NAAGJY-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d9b9ee3b-19d2-41b2-8fbe-dacbad1dbb3a.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-40-NAAGJY-10A (Blood Derived Normal), aliquot TARGET-40-NAAGJY-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d55ce330-654e-486a-8902-22c1ef506800

The open-access MAF lists 2 somatic variants for this specimen: 2 silent.
By variant classification: Silent 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- MSN | c.1002G>A p.E334= | Silent (SNP) | VAF 6/34 reads (18%) | catalogued as rs113359990, COSV64303140; called by mutect2, varscan2
- TICRR | c.2296C>T p.L766= | Silent (SNP) | VAF 24/74 reads (32%) | called by mutect2, varscan2
